Surgical pathology report (de-identified scan), TCGA case TCGA-FB-AAPQ, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Asterand, specimen TCGA-FB-AAPQ-01A (Primary Tumor).

[page 1 of 4]
TSS Patient ID:

Surgical Date:

Gross Description: C: Pancreatic mass: Received is one Whipple specimen composed of a

stomach (10.3 x 10 x 0.8 (wall thickness) cm), duodenum (25 cm in length x 4 cm in average diameter), gallbladder (11.5 x 4.5 x 2.2 cm), and pancreas (5.5 x 4.8 x 2.2 cm). The specimen is submitted with five designated margins. The long single blue suture is tumor invading the superior mesenteric vein; the looped blue suture identifies the superior mesenteric artery margin; the looped black suture identifies the deep radial margin; the long single black stitch identifies the portal vein margin, and the pair of double black sutures identifies the pancreatic neck margin.

The stomach has a proximal staple line that measures 8 cm in length. It is inked black and a representative section is submitted. The lesser curvature measures 7.5 cm in length, and the greater curvature measures 14.5 cm in length. The serosa is tan and mildly rough but unremarkable.

The attached omental fat measures 8.5 cm in greatest length. The specimen is opened along the lesser curvature to reveal regular rugae covered by light tan mucus. The mucosa is tan with a slightly nodular appearance (average 0.4 cm in diameter). Representative sections of stomach are submitted.

The pancreas has a rough, yellow, partially cauterized exterior. The neck margin is inked blue, and the remaining radial margins are inked black.

The five sutures are identified. Perpendicular sections of these margins are submitted. The specimen is serially sectioned to reveal a white, ill-defined, indurated mass in the head of the pancreas that extends to

ICD-O-3

Adenocarcinoma, duct
NOS 8500/3

Site. Pancreas head
C25.0
JFD 5/16/14

[page 2 of 4]
nearly the entire length of the organ. It measures 5 x 3.5 x 2.2 cm. In the inferior limit, the lesion is surrounded by yellow, partially fibrotic pancreatic parenchyma. The ampulla is patent to the common bile duct. The pancreatic main duct is obstructed by the pancreatic mass. However, it is patent at the pancreatic neck margin. Representative sections are submitted.

The duodenum has congested red serosa near the pancreas. It is otherwise unremarkable. The surgical margin is stapled. It is inked black, removed and submitted. The specimen is opened adjacent to the mesenteric border to reveal a 1.5-cm open defect with central ulceration that is located between the pylorus and the ampulla. The ulcer extends into the pancreas. It measures 1.1 cm in depth from the surface of the mucosa. It erodes nearly into the proximal limit of the prominent blue metal stent in the ampulla that measures 1.3 cm in diameter and 1.3 cm in length. The mucosa surrounding the ulcerative lesion and the proximal area of the stent is firm with a slight dusky appearance. There is an adjacent mass next to the ulcer that measures 1.5 x 0.8 cm to a height of 0.9 cm. It bridges between the ulcer and the stented bile duct. The mucosa distal to the bile duct is tan and edematous except for the most distal 11 cm of dusky mucosa.

The gallbladder has red-purple serosa with punctate areas of green. The attached area is rough with a scant amount of cauterized, yellow-lobular tissue. It is filled with viscous, red-brown fluid. The cystic duct measures 1.5 cm in length x 0.5 cm in diameter. There is a small duct that measures 0.3 cm in length x 0.2 cm in diameter 1.3 cm distal to the neck. This is either one of two candidate hepatic ducts or the cystic artery.

[page 3 of 4]
Near the insertion of the common bile duct to the pancreas, there is a circular defect that measures 0.4 cm in diameter. It is not certain if this is a surgical defect or if this is another candidate hepatic duct opening. Representative sections are submitted.

Sixteen possible pancreatic lymph nodes are dissected and range in from 0.5 x 0.3 x 0.3 cm to 2.7 x 1 x 1 cm. They are submitted in toto. Six possible greater curvature nodes are dissected and range from 0.2 x 0.2 x 0.2 cm to 0.8 x 0.6 x 0.6 cm. They are submitted in toto. No duodenal lymph nodes were found.

Microscopic Description:

Diagnosis Details: A: Pancreatic duct margin, biopsy:

- Ductal tissue, negative for carcinoma

B: Pancreatic margin, biopsy:

- Pancreatic parenchyma with chronic pancreatitis
- Negative for carcinoma (see comment)

C: Pancreatic mass, pancreaticoduodenectomy:

- Ductal adenocarcinoma invading duodenal mucosa and peripancreatic fat, excised

Comments:

Formatted Path Reports: PANCREAS TISSUE CHECKLIST

Specimen type: Pancreatoduodenectomy

Tumor site: Head

Tumor size: 5 x 3.5 x 2.2 cm

Histologic type: Adenocarcinoma, ductal type

Histologic grade: Moderately differentiated

[page 4 of 4]
Tumor extent: Other - Small intestine

Lymph nodes: 4/24 positive for metastasis (Regional 4/24)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Source: NCI Genomic Data Commons file 24882278-4990-4b6c-86be-1a537668dc0a (TCGA-FB-AAPQ.1944F530-8A4C-4DC8-94B2-DE1B6151B22D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).